TCGA case TCGA-09-0369 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: UCSF. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d9893c8-0de3-4b07-b0ba-a53019b23eb4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 1,082 days (3.0 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 56.7 years (20,705 days); Year of diagnosis: 2003; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: No macroscopic disease; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 8 days; Days to treatment end: 74 days; Number of cycles: 4; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 8 days; Days to treatment end: 74 days; Number of cycles: 4; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Docetaxel; Treatment intent type: Adjuvant; Days to treatment start: 78 days; Days to treatment end: 78 days; Number of cycles: 1; Treatment dose: 80 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 99 days; Days to treatment end: 99 days; Number of cycles: 1; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Treatment intent type: Adjuvant; Days to treatment start: 99 days; Days to treatment end: 99 days; Number of cycles: 1; Treatment dose: 1,000 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 298 days; Days to treatment end: 298 days; Number of cycles: 1; Treatment dose: 40 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Topotecan; Initial disease status: Recurrent Disease; Days to treatment start: 310 days; Days to treatment end: 446 days (1.2 years); Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 57.4 years (20,979 days); Days to diagnosis: 274 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 326 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 274 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 274 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,082 days (3.0 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Evidence of recurrence type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-09-0369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-09-0369-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-09-0369-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
- Samples TCGA-09-0369-10B, TCGA-09-0369-10C (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Carbo.
- Drug treatment 4: Pharmaceutical therapy drug name: taxol.
- Drug treatment 5: Pharmaceutical therapy drug name: Taxotere.
- Drug treatment 6: Pharmaceutical therapy drug name: doxil.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,082 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,082 days; disease-free interval: event (new tumor event after initially disease-free), 274 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 274 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-09-0369-01A-01D-0356-01): tumor purity 0.9, ploidy 2.64, whole-genome doublings 1.
